Gene-level copy-number profile of tumor specimen TCGA-YG-AA3O-06A from TCGA case TCGA-YG-AA3O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.5 years (23,907 days).
Specimen TCGA-YG-AA3O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.bbb1c2dc-daff-45b9-8aa2-1a4dc9b0bb9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YG-AA3O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8acc600d-f4c7-4681-96ab-cb05cb1cb7d7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 95; copy number 2: 8,439; copy number 3: 15,012; copy number 4: 26,486; copy number 5: 3,970; copy number 6: 1,584; copy number 7: 1,762; copy number 8: 106; copy number 10: 1,069; copy number 11: 787; copy number 12: 504.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YG-AA3O-06A-11D-A38F-01): tumor purity 0.62, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,360 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–57,773,381, 1,069 genes, copy number 10 (broad region; genes not listed).
- chr7:97,963,658–159,233,377, 1,287 genes, copy number 11–12 (broad region; genes not listed).
- chr16:81,739,097–82,011,481, 4 genes, copy number 11 (within-gene range 6–11): PLCG2, RN7SKP176, AC092142.2, SDR42E1.

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
